Somatic mutation profile of tumor specimen MBCProject_3135_T2_WES (aliquot MBCProject_3135_T2_WES_1) from CMI case MBCProject_3135, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.3 years (16,541 days).
Specimen MBCProject_3135_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84eafe3d-f5f4-4279-a959-947bb279d965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3135_SALIVA (Saliva), aliquot MBCProject_3135_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1694aa3f-28dc-42e3-a756-fa70653dee3f

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Intron 4, RNA 1, Frame Shift Ins 1, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAPNS1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as rs1159111926; called by muse, mutect2, varscan2
- DUSP12 | c.182C>G p.S61W | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1184210777, COSV100909779, COSV63411411; called by muse, mutect2, varscan2
- FAM71A | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs138474843; called by muse, mutect2
- HMCN1 | c.3655G>T p.V1219F | Missense Mutation (SNP) | VAF 50/712 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.15); catalogued as rs781473485; called by muse, mutect2
- KLC2 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.217); catalogued as rs762311202, COSV100270836; called by muse, mutect2, varscan2
- MCFD2 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV60178361; called by muse, mutect2
- NRCAM | c.1458C>G p.I486M (on ENST00000379028 / NM_001371124.1; = p.I480M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs747391115, COSV61035555; called by muse, mutect2, varscan2
- SLC41A2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs755953713, COSV99316108; called by muse, mutect2, varscan2
- STMN1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs757874144; called by muse, mutect2, varscan2
- TANC2 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67333183; called by muse, mutect2, varscan2
- TSPAN12 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 97/379 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.146); catalogued as rs1283326178, COSV56081587; called by muse, mutect2, varscan2
- ANOS1 | c.1069A>C p.N357H | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); called by muse, mutect2
- ATF6 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 50/749 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- BLK | c.1235T>C p.F412S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- C9 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2
- COL12A1 | c.2229G>A p.W743* | Nonsense Mutation (SNP) | VAF 25/256 reads (10%) | called by muse, mutect2, varscan2
- DNAAF2 | c.2412A>G p.I804M | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FASTK | c.1399A>G p.S467G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM2 | c.7030G>A p.D2344N | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GBA | c.1281A>C p.E427D | Missense Mutation (SNP) | VAF 39/572 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- KPNA4 | c.1116_1118dup p.M372dup | In Frame Ins (INS) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- RNF220 | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.775); called by muse, mutect2
- SCN7A | c.2567dup p.S857Vfs*3 | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- TEX14 | c.1904G>T p.C635F (on ENST00000240361 / NM_001201457.2; = p.C629F on NM_031272.5) | Missense Mutation (SNP) | VAF 30/577 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.142); called by muse, mutect2
- THAP5 | c.500_501del p.N167Tfs*3 (on ENST00000415914 / NM_001130475.3; = p.N125Tfs*3 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, varscan2
- FBLN2 | c.3204C>T p.C1068= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs113436041; called by mutect2, varscan2
- GRIN2C | c.3432G>A p.Q1144= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1302521416; called by muse, mutect2, varscan2
- KLK15 | c.99G>A p.Q33= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as rs1388965034; called by muse, mutect2, varscan2
- MARCHF6 | c.966A>G p.E322= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- POM121L2 | c.1113C>T p.N371= | Silent (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- ZYX | c.255A>T p.A85= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2
- AL359922.1 | c.348-35092G>T | Intron (SNP) | VAF 10/69 reads (14%) | catalogued as rs542282744; called by muse, mutect2, varscan2
- C16orf87 | c.-16G>C | 5'UTR (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- HLA-DOA | c.614-38C>T | Intron (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- IMMP1L | c.322-3546G>C | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- MST1L | n.939G>A | RNA (SNP) | VAF 25/264 reads (9%) | called by muse, varscan2
- ZNF525 | c.142+299C>G | Intron (SNP) | VAF 33/291 reads (11%) | called by muse, mutect2, varscan2
